Somatic mutation profile of tumor specimen TCGA-PJ-A8JU-01A (aliquot TCGA-PJ-A8JU-01A-11D-A35Z-10) from TCGA case TCGA-PJ-A8JU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 81.7 years (29,830 days).
Specimen TCGA-PJ-A8JU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c7829d9-7562-4322-b391-f36c9a8b86a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PJ-A8JU-10A (Blood Derived Normal), aliquot TCGA-PJ-A8JU-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeafa74f-66c0-42f2-bad9-0d8ac0f9f9ef

The open-access MAF lists 100 somatic variants for this specimen: 77 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 21, Frame Shift Del 8, In Frame Del 3, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC131160.1 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57701784; called by muse, mutect2, varscan2
- ACE | c.926C>G p.T309S | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as rs755789019, COSV99326460; called by muse, mutect2, varscan2
- ACTG2 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as COSV100608858; called by muse, mutect2, varscan2
- ADGRV1 | c.18623A>T p.E6208V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101315515; called by muse, varscan2
- AMBRA1 | c.1729T>C p.F577L (on ENST00000458649 / NM_001367468.1; = p.F487L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.294); catalogued as COSV100092798; called by muse, mutect2, varscan2
- AMBRA1 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100092801; called by muse, mutect2, varscan2
- ANK2 | c.9003T>A p.S3001R | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.165); catalogued as COSV99999821; called by muse, mutect2, varscan2
- ARG2 | c.680T>A p.I227N | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99373651; called by muse, mutect2, varscan2
- ARHGAP30 | c.2725T>G p.C909G (on ENST00000368013 / NM_001025598.2; = p.C698G on NM_181720.3) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.055); catalogued as COSV100920137; called by muse, mutect2, varscan2
- ARHGAP9 | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs368912616, COSV100712332; called by muse, mutect2, varscan2
- ATOH1 | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as COSV100024428; called by muse, mutect2, varscan2
- ATP6V1B2 | c.728T>A p.F243Y | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as COSV99369242; called by muse, mutect2, varscan2
- BRWD1 | c.236T>G p.L79W | Missense Mutation (SNP) | VAF 91/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100312837; called by muse, mutect2
- BSND | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.625); catalogued as COSV100987606; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV100575098; called by muse, mutect2, varscan2
- CES4A | c.974T>A p.V325E | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs3859072, COSV100109951; called by muse, mutect2, varscan2
- CILP2 | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs1046163953, COSV52275234; called by muse, mutect2, varscan2
- CMA1 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV51625995, COSV99157102; called by muse, mutect2, varscan2
- CPTP | c.33A>T p.K11N | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV100028016; called by muse, mutect2, varscan2
- CRB3 | c.170T>C p.I57T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs751651985, COSV100375177, COSV57569755; called by muse, mutect2, varscan2
- CREBZF | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99476114; called by muse, varscan2
- CRX | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as CD972156, COSV99704356; called by muse, mutect2, varscan2
- CYP1A2 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV100673853; called by muse, mutect2, varscan2
- DDX10 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs776492184, COSV59436570; called by muse, mutect2, varscan2
- DLX3 | c.208A>G p.N70D | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.777); catalogued as COSV101460515; called by muse, mutect2, varscan2
- DPYSL3 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100574897; called by muse, mutect2
- FMNL2 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99978938; called by muse, mutect2, varscan2
- FSTL4 | c.2462A>T p.N821I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV99531419; called by muse, mutect2, varscan2
- FUT5 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.1); catalogued as COSV99398532; called by muse, mutect2, varscan2
- GLCE | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.08); catalogued as COSV99962083; called by muse, mutect2, varscan2
- GLS | c.1496T>C p.M499T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV100289730; called by muse, mutect2, varscan2
- GLYR1 | c.1132del p.R378Gfs*23 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs780981191, COSV58927238, COSV58927479; called by mutect2, pindel, varscan2
- GOLGB1 | c.2245C>G p.L749V | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100510349; called by muse, mutect2, varscan2
- GRB7 | c.1453-2A>C p.X485_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100485377; called by muse, mutect2, varscan2
- HOXB13 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs770620686, COSV99285088; called by muse, mutect2, varscan2
- KLHL40 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99825334; called by muse, mutect2, varscan2
- KPNB1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99267780; called by muse, mutect2, varscan2
- MUC17 | c.5293G>A p.E1765K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as rs749046973, COSV100071646; called by muse, mutect2, varscan2
- MYBL1 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV101576475; called by muse, mutect2, varscan2
- MYH1 | c.3792G>C p.K1264N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV99874947; called by muse, mutect2, varscan2
- NAT8 | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV99721916; called by muse, mutect2, varscan2
- NR2F2 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101240921; called by muse, mutect2, varscan2
- OR13C2 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs75116810, COSV73377656; called by muse, mutect2, varscan2
- OR5B3 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.077); catalogued as rs1469208062, COSV100511869; called by muse, mutect2
- PCF11 | c.1769G>A p.S590N | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100017804; called by muse, mutect2, varscan2
- PITX1 | c.292A>G p.S98G | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99530502; called by muse, mutect2, varscan2
- PRKD2 | c.2254A>C p.N752H | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99354102; called by muse, mutect2, varscan2
- PYGO2 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.992); catalogued as rs267598059, COSV100868851, COSV63757468; called by muse, mutect2, varscan2
- RNF185 | c.57del p.S21Vfs*133 | Frame Shift Del (DEL) | VAF 43/105 reads (41%) | catalogued as COSV99067066; called by mutect2, pindel, varscan2
- SERPINE2 | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV99296364; called by muse, mutect2, varscan2
- SETD1A | c.1381dup p.R461Pfs*18 | Frame Shift Ins (INS) | VAF 13/63 reads (21%) | catalogued as rs1358737879; called by mutect2, pindel, varscan2
- SMC6 | c.2706T>G p.Y902* | Nonsense Mutation (SNP) | VAF 75/222 reads (34%) | catalogued as COSV100704779; called by muse, mutect2, varscan2
- SNURF | c.95C>A p.S32* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as COSV100577889; called by muse, mutect2, varscan2
- SOCS3 | c.89A>G p.E30G | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV100434446; called by muse, mutect2, varscan2
- TKT | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56244514, COSV99964857; called by muse, mutect2, varscan2
- TMEM158 | c.667A>C p.T223P | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100281515; called by muse, mutect2, varscan2
- TP53INP1 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710989; called by muse, mutect2, varscan2
- TTN | c.83126A>G p.N27709S (on ENST00000591111; = p.N20285S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | PolyPhen benign (0.007); catalogued as COSV59984986; called by muse, mutect2, varscan2
- UBIAD1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV65147491; called by muse, mutect2, varscan2
- USH2A | c.3806T>C p.L1269P | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100229226; called by muse, mutect2, varscan2
- USP32 | c.3774G>T p.K1258N | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100341454; called by muse, mutect2, varscan2
- ZG16B | c.260A>T p.K87I | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV101206745; called by muse, mutect2, varscan2
- ZGLP1 | c.449A>T p.K150M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV100593692; called by muse, mutect2, varscan2
- ZNF419 | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV99691808; called by muse, mutect2, varscan2
- ZNF71 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs759476055, COSV100045585; called by muse, mutect2, varscan2
- ANKRD50 | c.4245_4253del p.E1415_S1417del | In Frame Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- EFCAB13 | c.1331_1354del p.K444_K451del | In Frame Del (DEL) | VAF 36/172 reads (21%) | called by mutect2, pindel, varscan2
- GOT2 | c.1272del p.I425Ffs*32 | Frame Shift Del (DEL) | VAF 25/59 reads (42%) | called by mutect2, pindel, varscan2
- HOXD4 | c.407_422del p.W136Sfs*2 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- HTR1B | c.989del p.F330Sfs*6 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | called by mutect2, pindel, varscan2
- IGHV3-43 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- IL32 | c.516del p.L173Wfs*4 (on ENST00000396890 / NM_001308078.4; = p.L127Wfs*4 on NM_004221.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 62/141 reads (44%) | called by mutect2, varscan2
- KLK3 | c.630+2_630+3insTTT p.X210_splice | Splice Site (INS) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- MRC2 | c.755del p.N252Tfs*23 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- MUC16 | c.13019del p.V4340Afs*21 | Frame Shift Del (DEL) | VAF 30/81 reads (37%) | called by mutect2, pindel, varscan2
- SOX12 | c.103_111del p.T35_S37del | In Frame Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- TUBGCP3 | c.462dup p.G155Rfs*32 | Frame Shift Ins (INS) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- ATF4 | c.993C>A p.I331= | Silent (SNP) | VAF 60/114 reads (53%) | catalogued as rs189922789, COSV100307534; called by muse, mutect2, varscan2
- CLINT1 | c.1877A>G p.*626= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99753452; called by muse, mutect2
- CMA1 | c.183G>T p.V61= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV99157107; called by muse, mutect2, varscan2
- COL16A1 | c.1941T>C p.R647= | Silent (SNP) | VAF 83/252 reads (33%) | catalogued as COSV99593605; called by muse, mutect2, varscan2
- CUX1 | c.3984G>A p.R1328= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV99470505; called by muse, mutect2, varscan2
- FUT11 | c.1455C>A p.I485= | Silent (SNP) | VAF 49/76 reads (64%) | catalogued as COSV100226444, COSV100226523; called by muse, mutect2, varscan2
- IGKV1D-8 | c.249G>A p.R83= | Silent (SNP) | VAF 66/164 reads (40%) | catalogued as rs1272263436; called by muse, mutect2, varscan2
- INKA1 | c.303C>T p.G101= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100323511; called by muse, mutect2, varscan2
- KRT28 | c.219C>T p.G73= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV100137367; called by muse, mutect2, varscan2
- MED13 | c.5118C>A p.I1706= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV67261840; called by muse, mutect2, varscan2
- MN1 | c.2562A>G p.P854= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100179657; called by muse, mutect2, varscan2
- MTR | c.744G>A p.V248= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs1206033519, COSV100855768; called by muse, mutect2, varscan2
- NCOA1 | c.2022T>G p.G674= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV99945218; called by muse, mutect2, varscan2
- NCOA2 | c.2703T>C p.P901= | Silent (SNP) | VAF 42/147 reads (29%) | catalogued as COSV99144704; called by muse, mutect2, varscan2
- PABPC1 | c.1611T>C p.V537= | Silent (SNP) | VAF 82/242 reads (34%) | catalogued as COSV100589323, COSV100589966; called by muse, mutect2, varscan2
- PHIP | c.4557G>A p.E1519= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV99243445, COSV99244808; called by muse, mutect2, varscan2
- PTPRN | c.78C>T p.S26= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs1402585163, COSV99833692; called by muse, mutect2, varscan2
- STAG1 | c.2352T>C p.N784= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV52614769, COSV99364459; called by muse, mutect2, varscan2
- STAU1 | c.1707A>G p.G569= (on ENST00000371856 / NM_001319135.1; = p.G488= on NM_004602.3) | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100574267; called by muse, mutect2, varscan2
- STOX1 | c.1938C>A p.A646= | Silent (SNP) | VAF 45/63 reads (71%) | catalogued as COSV100057542; called by muse, mutect2, varscan2
- TRHDE | c.1932T>C p.T644= | Silent (SNP) | VAF 65/123 reads (53%) | catalogued as COSV99669197; called by muse, mutect2, varscan2
- FGFR3 | chr4:1807418 T>C | 3'Flank (SNP) | VAF 6/18 reads (33%) | catalogued as rs774898004, COSV53399033; called by muse, varscan2
- GCDH | c.*185A>G | 3'UTR (SNP) | VAF 36/136 reads (26%) | catalogued as rs376334735, COSV99535719; called by muse, mutect2
